Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3548, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3548-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with tumor-free oral and aboral resection margins, as well as an ulcerated, moderately differentiated adenocarcinoma in the region of the Bauhin's valve and the bordering cecum with infiltration of the perimuscular adipose tissue, and with four regional lymph node metastases (G2, pT3 L1 V0 local R0 pN2 4/23).

Source: NCI Genomic Data Commons file bf20eab5-a834-4bf4-88ba-7fbe31e6c7b4 (TCGA-AA-3548.D2B49072-6158-48AE-8C9B-1F0BA0D2660A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).